Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A688, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A688-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #: 3
SEX: F

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Source of Specimen: Right adrenal gland. Operative Procedure:
Adrenalectomy/right adrenal gland.

PROCEDURE: SPGD

VERIFIED BY:

1. "Right adrenal gland". A 225 gram, well encapsulated soft bright yellow soft partially cystic mass with focal hemorrhage 7.5 x 5.4 x 6.7 cm. There is a thin strip of normal identifiable adrenal gland at one periphery. 1.2 x 0.3 cm. Capsule inked black.
1A. Representative sections with capsule.
1B. Representative section and normal rim of adrenal.
1C-F. Representative section submitted.

PROCEDURE: SPDX

VERIFIED BY

1. Right adrenal gland, resection: Pheochromocytoma. Margins negative.

I, , the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

H/PA Discrepancy		/

Source: NCI Genomic Data Commons file 900cd2ab-9956-4c60-a90a-92c1f9642645 (TCGA-RW-A688.6288EF26-B19E-452C-A6E2-91F832373C77.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).